Somatic mutation profile of tumor specimen MP2PRT-PATFZU-TMP1-A (aliquot MP2PRT-PATFZU-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATFZU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (721 days).
Specimen MP2PRT-PATFZU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 444ba1a1-9a8c-4c7e-a4f1-7284a949650e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATFZU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATFZU-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c013bd6-43ec-465f-bc80-375b21c5b3c9

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLK2 | c.489G>T p.E163D | Missense Mutation (SNP) | VAF 95/263 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV57569629; called by muse, mutect2, varscan2
- TENM3 | c.5260G>C p.E1754Q | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV69299753; called by muse, mutect2
- GRM1 | c.2371A>G p.M791V | Missense Mutation (SNP) | VAF 164/410 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MRPL49 | c.230-1G>A p.X77_splice | Splice Site (SNP) | VAF 13/278 reads (5%) | called by muse, mutect2
- SLC22A3 | c.362C>G p.S121W | Missense Mutation (SNP) | VAF 20/583 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2
